Gene-level copy-number profile of tumor specimen MP2PRT-PARMIB-TMP1-A from MP2PRT case MP2PRT-PARMIB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,498 days).
Specimen MP2PRT-PARMIB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 241847bd-1a84-4073-bf57-1cdc7922f370.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARMIB-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/c8df0160-3d54-46c2-a2f9-dbfd0d52d7fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 294; copy number 1: 39; copy number 2: 34,772; copy number 3: 78; copy number 4: 169; copy number 5: 22,257; copy number 6: 9; copy number 8: 762.

Homozygous deletions (total copy number 0; autosomes only): 294 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 37 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV2-28, IGKV2-29, IGKV2-30.
- chr3:25,664,873–25,687,123, 2 genes (within-gene range 0–2): MIR4442, CRIP1P2.
- chr3:157,146,508–157,160,760, 2 genes: CCNL1, Y_RNA.
- chr12:9,852,984–13,982,002, 135 genes (broad region; genes not listed).
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–5) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–5): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20,684 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,246,915, 706 genes, copy number 5 (broad region; genes not listed).
- chr4:51,843,000–190,092,279, 1,850 genes, copy number 5 (broad region; genes not listed).
- chr6:105,919–170,738,536, 2,961 genes, copy number 5 (broad region; genes not listed).
- chr7:38,269,491–38,311,808, 7 genes, copy number 6 (within-gene range 2–6): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr8:64,091–145,066,685, 2,404 genes, copy number 5 (broad region; genes not listed).
- chr10:14,061–133,778,699, 2,261 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–22,423,042, 262 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:22,515,623–105,669,843, 1,759 genes, copy number 5–8 (within-gene range 0–8) (broad region; genes not listed).
- chr14:106,482,435–106,521,073, 7 genes, copy number 5 (within-gene range 0–5): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,556,936–106,879,812, 51 genes, copy number 5: IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:22,495,570–101,979,093, 2,058 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–83,240,804, 3,020 genes, copy number 5 (broad region; genes not listed).
- chr18:45,034–80,247,514, 1,199 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–9,018,670, 37 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3.
- chr21:9,325,013–46,691,226, 750 genes, copy number 5–8 (broad region; genes not listed).
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
